Somatic mutation profile of tumor specimen HCM-CSHL-0838-C18-06A (aliquot HCM-CSHL-0838-C18-06A-11D-A85L-36) from HCMI case HCM-CSHL-0838-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.6 years (21,407 days).
Specimen HCM-CSHL-0838-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c81a956b-1d68-42df-9709-ddce98af7555.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0838-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0838-C18-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8225de5-1570-42c2-ae03-eaf67b62cd9d

The open-access MAF lists 170 somatic variants for this specimen: 128 protein-altering or splice-affecting, 34 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 34, Intron 5, Splice Region 4, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1, 5'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 58/512 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 153/596 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 124/736 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs372679186; called by muse, mutect2, varscan2
- ADAMTS12 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 139/671 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1475880471; called by muse, mutect2, varscan2
- BEST3 | c.1955A>C p.K652T | Missense Mutation (SNP) | VAF 107/531 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV100437572; called by muse, mutect2, varscan2
- BTAF1 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 63/558 reads (11%) | catalogued as COSV56437564; called by muse, mutect2, varscan2
- CAPRIN2 | c.1062G>A p.E354= | Splice Region (SNP) | VAF 102/443 reads (23%) | catalogued as rs753169505; called by muse, mutect2, varscan2
- CCDC39 | c.1139T>C p.M380T | Missense Mutation (SNP) | VAF 60/694 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1292687816; called by muse, mutect2
- CCNB3 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 101/1086 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782584766; called by muse, mutect2
- CDH11 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 165/681 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51762283; called by muse, mutect2, varscan2
- CFAP52 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 77/359 reads (21%) | catalogued as rs369634065, COSV100235430; called by muse, mutect2, varscan2
- CXXC4 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 126/662 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.992); catalogued as rs934612364; called by muse, mutect2, varscan2
- CYP19A1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 188/1017 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs761722363, COSV53057118; called by muse, mutect2, varscan2
- DISP1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 60/696 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as rs191290309, COSV52658137; called by muse, mutect2
- DRC1 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 163/780 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1472262198, COSV99717191; called by muse, mutect2, varscan2
- EDNRB | c.338G>A p.R113Q (on ENST00000377211 / NM_001201397.1; = p.R23Q on NM_000115.5) | Missense Mutation (SNP) | VAF 174/962 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.039); catalogued as COSV100526646; called by muse, mutect2, varscan2
- ELOA | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 145/594 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69309342; called by muse, mutect2, varscan2
- EMC10 | c.678C>T p.Y226= | Splice Region (SNP) | VAF 107/530 reads (20%) | catalogued as rs372179800; called by muse, mutect2, varscan2
- FAM47B | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 232/1335 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1389383523, COSV100264435, COSV61452705; called by muse, mutect2, varscan2
- FAM47C | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 126/1072 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs138293293, COSV100792387, COSV100792939; called by muse, mutect2, varscan2
- HAS1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 207/963 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs747388837; called by muse, mutect2, varscan2
- HHIPL1 | c.1571A>G p.H524R | Missense Mutation (SNP) | VAF 138/691 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1406824774; called by muse, mutect2, varscan2
- HTR1A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 94/703 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV60501935; called by muse, mutect2, varscan2
- HYDIN | c.11495G>A p.R3832H | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs7198721; called by muse, mutect2, varscan2
- KCTD16 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 86/701 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV72578208; called by muse, mutect2, varscan2
- KDM6A | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 161/741 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65041880; called by muse, mutect2, varscan2
- KMT5B | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 84/551 reads (15%) | catalogued as COSV100069992, COSV58568821; called by muse, mutect2, varscan2
- LAMA3 | c.9560G>A p.R3187H (on ENST00000313654 / NM_198129.4; = p.R1578H on NM_000227.6) | Missense Mutation (SNP) | VAF 60/489 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs143170913; called by muse, mutect2, varscan2
- MORC1 | c.2328G>T p.L776F | Missense Mutation (SNP) | VAF 110/466 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.367); catalogued as rs1296771765; called by mutect2, varscan2
- NBEAL2 | c.6179G>A p.R2060H | Missense Mutation (SNP) | VAF 177/859 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs764406411; called by muse, mutect2, varscan2
- NLRP8 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 51/448 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs547425685; called by muse, mutect2, varscan2
- OBSCN | c.3109C>T p.R1037W | Missense Mutation (SNP) | VAF 185/802 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs202144178; called by muse, mutect2, varscan2
- PA2G4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 78/713 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as rs1468032069; called by muse, mutect2, varscan2
- PCDHA4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 112/882 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs13189658, COSV63539039; called by muse, mutect2, varscan2
- PCDHA5 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 191/881 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1554128404, COSV65350329; called by muse, mutect2, varscan2
- PRKD1 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761962478; called by muse, mutect2, varscan2
- PRR23C | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 154/940 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1200375371; called by muse, mutect2, varscan2
- RIMS3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 85/636 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV65503872, COSV65504931; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 96/414 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1255028692; called by muse, mutect2, varscan2
- SLC35E1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 138/641 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258822687; called by muse, mutect2, varscan2
- SULF2 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 211/666 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767855983; called by muse, mutect2, varscan2
- SYNE1 | c.10978G>T p.A3660S (on ENST00000367255 / NM_182961.4; = p.A3645S on NM_033071.3) | Missense Mutation (SNP) | VAF 128/725 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55021144; called by muse, mutect2, varscan2
- TRDN | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 127/752 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1278830566; called by muse, mutect2, varscan2
- TRIM24 | c.3115C>T p.R1039C (on ENST00000343526 / NM_015905.3; = p.R1005C on NM_003852.4) | Missense Mutation (SNP) | VAF 107/501 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166324119, COSV58978097; called by muse, mutect2, varscan2
- USP19 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 102/739 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1242657943; called by muse, mutect2, varscan2
- ZFYVE9 | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 72/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760825781, COSV55095322; called by muse, mutect2, varscan2
- ZNF814 | c.1603C>G p.L535V | Missense Mutation (SNP) | VAF 99/818 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101457231; called by muse, mutect2, varscan2
- ZNF835 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 170/719 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV101606417; called by muse, mutect2, varscan2
- ABCC12 | c.278T>G p.F93C | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACADL | c.191T>A p.V64E | Missense Mutation (SNP) | VAF 21/455 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ADCY1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 25/922 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- ALYREF | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 92/946 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- ANKRD55 | c.1423A>C p.S475R | Missense Mutation (SNP) | VAF 77/706 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC | c.3516_3522dup p.Q1175Cfs*6 | Frame Shift Ins (INS) | VAF 87/492 reads (18%) | called by mutect2, varscan2
- APC | c.4260del p.S1421Vfs*52 | Frame Shift Del (DEL) | VAF 77/634 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.2156G>T p.S719I (on ENST00000359920 / NM_001130955.2; = p.S615I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/702 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- B3GNT3 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 92/801 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB6 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 71/931 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- BRWD1 | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BRWD3 | c.2711C>A p.T904N | Missense Mutation (SNP) | VAF 74/924 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- CACNA2D1 | c.2693A>G p.Y898C (on ENST00000356253 / NM_001366867.1; = p.Y886C on NM_000722.4) | Missense Mutation (SNP) | VAF 76/553 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CATSPER4 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 84/674 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC166 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 120/1384 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- CCDC183 | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 121/414 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CHRDL1 | c.425C>G p.S142W (on ENST00000372045; = p.S148W on NM_145234.4) | Missense Mutation (SNP) | VAF 53/861 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CSMD1 | c.583T>C p.W195R | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX2 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 54/660 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- DALRD3 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 161/796 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBX2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 84/866 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2
- DGKH | c.3268G>T p.V1090L | Missense Mutation (SNP) | VAF 26/879 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- DNAH17 | c.8358T>G p.I2786M | Missense Mutation (SNP) | VAF 132/706 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNAH9 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 128/424 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DRD3 | c.1025G>T p.W342L | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4G3 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXD3 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 127/897 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FABP7 | c.351C>T p.T117= | Splice Region (SNP) | VAF 38/506 reads (8%) | called by muse, mutect2
- FAM122A | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 185/700 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FANCL | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 27/484 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- FLNA | c.5399A>T p.K1800M (on ENST00000369850 / NM_001110556.2; = p.K1792M on NM_001456.3) | Missense Mutation (SNP) | VAF 270/1010 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FNDC1 | c.4319T>A p.I1440N | Missense Mutation (SNP) | VAF 89/838 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by mutect2, varscan2
- GLI2 | c.3037A>T p.S1013C (on ENST00000361492 / NM_001374353.1; = p.S1030C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/1396 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR156 | c.587G>C p.S196T | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- HBP1 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- HCCS | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 68/1164 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2
- HS3ST2 | c.694T>G p.S232A | Missense Mutation (SNP) | VAF 95/853 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HUWE1 | c.1957+1G>A p.X653_splice | Splice Site (SNP) | VAF 59/608 reads (10%) | called by muse, mutect2
- HYDIN | c.9326T>C p.L3109P | Missense Mutation (SNP) | VAF 68/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IFT52 | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 84/1102 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- KLHL34 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 274/1084 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by mutect2, varscan2
- L1CAM | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 51/1370 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.205); called by muse, mutect2
- LAS1L | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 360/1252 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LRRK2 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 91/521 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MAGEC1 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 80/1510 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MAP2 | c.4052C>A p.P1351Q | Missense Mutation (SNP) | VAF 16/562 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K9 | c.2772G>C p.E924D (on ENST00000554752 / NM_001284230.1; = p.E938D on NM_033141.4) | Missense Mutation (SNP) | VAF 74/907 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- MTARC1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 74/552 reads (13%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NEFM | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 83/593 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NLRP13 | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 76/739 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- NONO | c.1071_1094del p.E361_E368del | In Frame Del (DEL) | VAF 138/654 reads (21%) | called by mutect2, varscan2
- NUP188 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 45/476 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPHN1 | c.1374A>T p.E458D | Missense Mutation (SNP) | VAF 52/836 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDHB11 | c.2294A>C p.K765T | Missense Mutation (SNP) | VAF 107/589 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PGLYRP2 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 82/651 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- PHIP | c.5429T>G p.L1810W | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLEKHG4B | c.1048G>A p.E350K (on ENST00000283426; = p.E706K on NM_052909.5) | Missense Mutation (SNP) | VAF 50/517 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PRND | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 84/996 reads (8%) | called by muse, mutect2
- RAD54B | c.624del p.Q209Sfs*78 | Frame Shift Del (DEL) | VAF 241/819 reads (29%) | called by mutect2, pindel, varscan2
- RBBP6 | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 101/591 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RUFY4 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 94/822 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SCP2D1 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 44/682 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- SLC25A46 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 66/678 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- SNX9 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 98/608 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPANXD | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 102/1356 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2
- TAB3 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 280/1022 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TCAF1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 174/827 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR7 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 82/799 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR8 | c.1438G>T p.A480S (on ENST00000218032 / NM_138636.5; = p.A498S on NM_016610.4) | Missense Mutation (SNP) | VAF 70/816 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TMEM115 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 80/781 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TUBD1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 71/959 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE3C | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 88/478 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- USP4 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 69/653 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- USP9X | c.1317A>G p.A439= | Splice Region (SNP) | VAF 30/599 reads (5%) | called by muse, mutect2
- UXT | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 222/898 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF124 | c.781C>A p.P261T (on ENST00000543802 / NM_001297568.1; = p.P199T on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/790 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF273 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 98/519 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF449 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 36/945 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.438); called by muse, mutect2
- ZNF765 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 40/615 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); called by muse, mutect2
- ZNF829 | c.747del p.F249Lfs*39 | Frame Shift Del (DEL) | VAF 156/738 reads (21%) | called by mutect2, pindel, varscan2
- AP1B1 | c.519C>T p.N173= | Silent (SNP) | VAF 73/382 reads (19%) | called by muse, mutect2, varscan2
- ARL15 | c.132C>A p.G44= | Silent (SNP) | VAF 75/708 reads (11%) | catalogued as rs943012169; called by muse, mutect2
- CEACAM3 | c.321G>T p.L107= | Silent (SNP) | VAF 60/653 reads (9%) | called by muse, mutect2
- CFAP43 | c.3636G>A p.V1212= | Silent (SNP) | VAF 113/432 reads (26%) | called by muse, mutect2, varscan2
- DCAF1 | c.45T>A p.T15= | Silent (SNP) | VAF 111/585 reads (19%) | called by muse, mutect2, varscan2
- DIAPH3 | c.2919C>T p.N973= (on ENST00000400324 / NM_001042517.2; = p.N710= on NM_030932.3) | Silent (SNP) | VAF 92/634 reads (15%) | called by muse, mutect2, varscan2
- DMRTB1 | c.318C>T p.D106= | Silent (SNP) | VAF 97/909 reads (11%) | called by muse, mutect2, varscan2
- DNAH5 | c.7482G>A p.A2494= | Silent (SNP) | VAF 194/949 reads (20%) | called by muse, mutect2, varscan2
- FAT3 | c.4083C>T p.T1361= | Silent (SNP) | VAF 133/796 reads (17%) | called by muse, mutect2, varscan2
- FOXI2 | c.831G>A p.P277= | Silent (SNP) | VAF 184/731 reads (25%) | catalogued as rs977042029; called by muse, varscan2
- GPC4 | c.660T>G p.T220= | Silent (SNP) | VAF 77/1328 reads (6%) | called by muse, mutect2
- HTT | c.2352C>T p.R784= | Silent (SNP) | VAF 66/651 reads (10%) | catalogued as rs748426062; called by muse, mutect2, varscan2
- JPH4 | c.852C>T p.G284= | Silent (SNP) | VAF 85/798 reads (11%) | catalogued as COSV62509741; called by muse, mutect2, varscan2
- KCNH8 | c.2691C>T p.N897= | Silent (SNP) | VAF 79/761 reads (10%) | catalogued as rs751554750; called by muse, mutect2
- KIAA1210 | c.1773G>A p.K591= | Silent (SNP) | VAF 98/1354 reads (7%) | called by muse, mutect2
- KRT1 | c.519C>T p.I173= | Silent (SNP) | VAF 118/593 reads (20%) | called by muse, mutect2, varscan2
- LRP1 | c.5505C>T p.V1835= | Silent (SNP) | VAF 132/618 reads (21%) | called by muse, mutect2, varscan2
- MYO15A | c.324G>A p.V108= | Silent (SNP) | VAF 23/724 reads (3%) | catalogued as COSV52753415; called by muse, mutect2
- PAPPA2 | c.2493C>T p.D831= | Silent (SNP) | VAF 75/754 reads (10%) | called by muse, mutect2, varscan2
- PBRM1 | c.5043C>T p.R1681= (on ENST00000296302 / NM_001366071.2; = p.R1574= on NM_018313.5) | Silent (SNP) | VAF 56/547 reads (10%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1782C>T p.G594= | Silent (SNP) | VAF 51/1220 reads (4%) | catalogued as rs200857606; called by muse, mutect2
- POLD4 | c.153G>A p.Q51= | Silent (SNP) | VAF 74/960 reads (8%) | catalogued as rs145225786; called by muse, mutect2
- PRSS36 | c.978G>A p.G326= | Silent (SNP) | VAF 77/610 reads (13%) | called by muse, mutect2, varscan2
- SDK1 | c.6552G>A p.P2184= | Silent (SNP) | VAF 237/1120 reads (21%) | catalogued as rs764760882, COSV67389853; called by muse, mutect2, varscan2
- SEC63 | c.1890C>A p.T630= | Silent (SNP) | VAF 45/525 reads (9%) | called by muse, mutect2
- SH3D19 | c.1101C>T p.S367= | Silent (SNP) | VAF 164/667 reads (25%) | called by muse, mutect2, varscan2
- SHISA2 | c.264C>T p.C88= | Silent (SNP) | VAF 78/1104 reads (7%) | called by muse, mutect2
- SI | c.3990T>C p.C1330= | Silent (SNP) | VAF 120/472 reads (25%) | called by muse, mutect2, varscan2
- SLC35F2 | c.9A>C p.A3= | Silent (SNP) | VAF 87/613 reads (14%) | catalogued as rs371255646; called by muse, mutect2, varscan2
- SLFN13 | c.396T>G p.S132= | Silent (SNP) | VAF 83/624 reads (13%) | called by muse, mutect2, varscan2
- TBXA2R | c.837C>T p.A279= | Silent (SNP) | VAF 64/644 reads (10%) | catalogued as rs758529770; called by muse, mutect2, varscan2
- TGM1 | c.642C>T p.N214= | Silent (SNP) | VAF 123/773 reads (16%) | catalogued as rs761501855; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIO | c.7422C>T p.P2474= | Silent (SNP) | VAF 238/1071 reads (22%) | catalogued as rs772235342; called by muse, mutect2, varscan2
- ZNF850 | c.886C>T p.L296= | Silent (SNP) | VAF 53/735 reads (7%) | called by muse, mutect2
- AGK | c.141+166C>A | Intron (SNP) | VAF 72/762 reads (9%) | called by muse, mutect2
- AL627230.3 | c.76-25C>A | Intron (SNP) | VAF 40/1036 reads (4%) | called by muse, mutect2
- FAM217A | c.-142G>C | 5'UTR (SNP) | VAF 59/781 reads (8%) | catalogued as COSV99212717; called by muse, mutect2
- MRPL21 | c.553+110G>A | Intron (SNP) | VAF 193/1151 reads (17%) | called by muse, mutect2, varscan2
- NAXD | chr13:110615619 C>G | 5'Flank (SNP) | VAF 117/1293 reads (9%) | called by muse, mutect2
- PEG10 | c.*334C>T | 3'UTR (SNP) | VAF 63/770 reads (8%) | called by muse, mutect2
- RBM44 | c.-98-2478C>A | Intron (SNP) | VAF 112/515 reads (22%) | called by muse, mutect2, varscan2
- VAPA | c.418-5402C>T | Intron (SNP) | VAF 93/644 reads (14%) | called by muse, mutect2, varscan2
